Somatic mutation profile of tumor specimen TCGA-CW-5589-01A (aliquot TCGA-CW-5589-01A-01D-1534-10) from TCGA case TCGA-CW-5589, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 52.9 years (19,312 days).
Specimen TCGA-CW-5589-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3039a522-c08d-4e85-a2c0-7cbb72b201dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CW-5589-11A (Solid Tissue Normal), aliquot TCGA-CW-5589-11A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/667c9244-c59a-4803-b453-e9e16dff25ad

The open-access MAF lists 66 somatic variants for this specimen: 50 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 15, Splice Site 4, Frame Shift Del 3, Nonsense Mutation 3, Frame Shift Ins 2, In Frame Ins 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APLF | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 93/410 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV58142575; called by muse, mutect2, varscan2
- ARMCX3 | c.926T>A p.F309Y | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV57869718; called by muse, mutect2, varscan2
- BDP1 | c.5980G>A p.D1994N | Missense Mutation (SNP) | VAF 89/413 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.714); catalogued as rs922151270, COSV62428971; called by muse, mutect2, varscan2
- C20orf85 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1389714012, COSV64519037; called by muse, mutect2, varscan2
- CDC14A | c.1267G>C p.G423R | Missense Mutation (SNP) | VAF 169/572 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.052); catalogued as COSV60555348; called by muse, mutect2, varscan2
- CMYA5 | c.6688G>C p.A2230P | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as COSV71404102; called by muse, mutect2, varscan2
- DCLRE1A | c.1543G>A p.V515I | Missense Mutation (SNP) | VAF 79/269 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as COSV63748177; called by muse, mutect2, varscan2
- DEAF1 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 20/149 reads (13%) | catalogued as COSV58605821; called by muse, mutect2, varscan2
- DPF3 | c.811A>G p.M271V | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1411834661, COSV63498798; called by muse, mutect2
- DTX1 | c.1174C>G p.P392A | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV57495674, COSV57501465; called by muse, mutect2, varscan2
- EBF3 | c.1723C>T p.P575S (on ENST00000355311 / NM_001375392.1; = p.P530S on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as rs764680863, COSV62471985; called by muse, varscan2
- F5 | c.452A>T p.E151V | Missense Mutation (SNP) | VAF 82/405 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.018); catalogued as COSV63120540; called by muse, mutect2, varscan2
- FIG4 | c.1328A>C p.K443T | Missense Mutation (SNP) | VAF 192/779 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV57785117; called by muse, mutect2, varscan2
- HIP1R | c.2663A>G p.E888G | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV53439423; called by muse, mutect2, varscan2
- KMT2E | c.5006A>G p.H1669R | Missense Mutation (SNP) | VAF 96/343 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV57569637; called by muse, mutect2, varscan2
- LATS2 | c.1788C>G p.S596R | Missense Mutation (SNP) | VAF 90/364 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.482); catalogued as COSV66873626; called by muse, mutect2, varscan2
- MTHFD2 | c.472C>G p.H158D | Missense Mutation (SNP) | VAF 33/976 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV51201013; called by muse, mutect2
- NEK5 | c.1282C>G p.R428G | Missense Mutation (SNP) | VAF 51/489 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62878887, COSV62879473; called by muse, mutect2, varscan2
- NIPBL | c.5011-1G>T p.X1671_splice | Splice Site (SNP) | VAF 140/553 reads (25%) | catalogued as COSV56942548; called by muse, mutect2, varscan2
- NLRP9 | c.1579C>T p.L527F | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.533); catalogued as COSV60459727; called by muse, mutect2, varscan2
- OR5AR1 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 85/336 reads (25%) | catalogued as COSV57252831, COSV57253262; called by muse, mutect2, varscan2
- PBRM1 | c.1302-1G>T p.X434_splice | Splice Site (SNP) | VAF 29/267 reads (11%) | catalogued as COSV56261520; called by muse, mutect2, varscan2
- PCNX1 | c.4816C>G p.L1606V | Missense Mutation (SNP) | VAF 100/386 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53089376; called by muse, mutect2, varscan2
- POGLUT1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 14/424 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV55155363; called by muse, mutect2
- POU3F4 | c.91T>C p.F31L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV64537803; called by muse, mutect2, varscan2
- RAB3A | c.371C>G p.S124* | Nonsense Mutation (SNP) | VAF 35/116 reads (30%) | catalogued as COSV55851924, COSV55852014; called by muse, mutect2, varscan2
- RANBP2 | c.2871G>C p.R957S | Missense Mutation (SNP) | VAF 80/346 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as COSV51696152; called by muse, mutect2
- RARA | c.644A>G p.E215G | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.378); catalogued as COSV54189876; called by muse, mutect2, varscan2
- RSKR | c.494C>A p.P165H | Missense Mutation (SNP) | VAF 73/293 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56380754; called by muse, mutect2, varscan2
- SH3GLB2 | c.626T>G p.L209R | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); catalogued as COSV65330164; called by muse, mutect2, varscan2
- SLC8A1 | c.168G>C p.K56N | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as COSV60471336; called by muse, mutect2
- SPAG5 | c.3209A>T p.E1070V | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56885506; called by muse, mutect2, varscan2
- SSH3 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.495); catalogued as rs747587103, COSV57383355; called by muse, mutect2, varscan2
- ST18 | c.362G>T p.C121F | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV52484760; called by muse, mutect2, varscan2
- SUZ12 | c.1430A>C p.N477T | Missense Mutation (SNP) | VAF 90/278 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.3); catalogued as COSV59498082; called by muse, mutect2, varscan2
- TMTC2 | c.2332-1G>C p.X778_splice | Splice Site (SNP) | VAF 88/352 reads (25%) | catalogued as COSV58259967; called by muse, mutect2, varscan2
- TRIOBP | c.1478G>A p.S493N | Missense Mutation (SNP) | VAF 178/396 reads (45%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs4821700; ClinVar: likely benign / benign; called by muse, varscan2
- UBE3A | c.561C>G p.D187E | Missense Mutation (SNP) | VAF 181/778 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as COSV51661241; called by muse, mutect2, varscan2
- ZHX3 | c.2152G>A p.A718T | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.058); catalogued as COSV58380768; called by muse, mutect2, varscan2
- ZNF546 | c.605T>C p.I202T | Missense Mutation (SNP) | VAF 50/359 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs766958493, COSV61257189; called by muse, mutect2, varscan2
- ALK | c.2300del p.K767Rfs*23 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, varscan2
- BLVRA | c.82_83del p.R28Efs*24 | Frame Shift Del (DEL) | VAF 60/250 reads (24%) | called by mutect2, varscan2
- CRIP3 | c.503dup p.V169Sfs*32 (on ENST00000274990; = p.V169Sfs*29 on NM_206922.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 7/31 reads (23%) | called by mutect2, varscan2
- KRT27 | c.1191-4_1191-2dup p.X397_splice | Splice Site (INS) | VAF 179/722 reads (25%) | called by mutect2, varscan2
- NUP85 | c.132dup p.S45Ifs*15 | Frame Shift Ins (INS) | VAF 66/205 reads (32%) | called by mutect2, varscan2
- PGM5 | c.1249A>T p.I417F | Missense Mutation (SNP) | VAF 61/212 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- POLH | c.1273_1275dup p.C425dup | In Frame Ins (INS) | VAF 88/332 reads (27%) | called by mutect2, varscan2
- PSG9 | c.207del p.E71Kfs*2 | Frame Shift Del (DEL) | VAF 78/282 reads (28%) | called by mutect2, varscan2
- TMEM63B | c.1370_1378del p.T457_D459del | In Frame Del (DEL) | VAF 64/322 reads (20%) | called by mutect2, varscan2
- TRGC2 | c.227C>G p.T76R | Missense Mutation (SNP) | VAF 309/1195 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ADAMTSL3 | c.4983C>T p.D1661= | Silent (SNP) | VAF 22/454 reads (5%) | catalogued as COSV54436677; called by muse, mutect2
- ARHGAP39 | c.2589C>T p.A863= (on ENST00000276826 / NM_001308208.2; = p.A894= on NM_025251.2) | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV52767171; called by muse, mutect2, varscan2
- ATR | c.1035T>A p.A345= | Silent (SNP) | VAF 110/353 reads (31%) | catalogued as COSV63383957; called by muse, mutect2, varscan2
- CUBN | c.2691A>C p.S897= | Silent (SNP) | VAF 96/340 reads (28%) | catalogued as COSV64708087; called by muse, mutect2, varscan2
- DENND4A | c.537C>T p.V179= | Silent (SNP) | VAF 122/471 reads (26%) | catalogued as rs765578634, COSV71265204; called by muse, mutect2, varscan2
- GTF2A1 | c.102G>A p.V34= | Silent (SNP) | VAF 136/584 reads (23%) | catalogued as COSV53336253; called by muse, mutect2, varscan2
- KAZN | c.714C>T p.A238= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV63206694; called by muse, mutect2, varscan2
- KPNA2 | c.1158C>G p.L386= | Silent (SNP) | VAF 24/338 reads (7%) | catalogued as rs782240404, COSV57856870; called by muse, mutect2
- NLGN2 | c.1353G>C p.L451= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV57208994; called by muse, mutect2, varscan2
- POTEA | c.399G>A p.R133= | Silent (SNP) | VAF 102/437 reads (23%) | called by muse, mutect2, varscan2
- RAB8B | c.285C>G p.S95= | Silent (SNP) | VAF 118/389 reads (30%) | catalogued as COSV58489078; called by muse, mutect2
- SEMA4A | c.2088A>G p.S696= | Silent (SNP) | VAF 50/194 reads (26%) | catalogued as COSV61772061; called by muse, mutect2
- STAG1 | c.3333C>A p.P1111= | Silent (SNP) | VAF 89/290 reads (31%) | catalogued as COSV52601847; called by muse, mutect2, varscan2
- SYK | c.108T>C p.D36= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs1225805514, COSV65325256; called by muse, mutect2
- TM6SF2 | c.426C>G p.L142= | Silent (SNP) | VAF 39/169 reads (23%) | catalogued as rs892478039, COSV66984938; called by muse, mutect2, varscan2
- BRWD1 | c.6571+70G>T | Intron (SNP) | VAF 177/694 reads (26%) | catalogued as COSV60892791; called by muse, mutect2, varscan2
